Somatic mutation profile of tumor specimen TCGA-DJ-A3UV-01A (aliquot TCGA-DJ-A3UV-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 18.8 years (6,850 days).
Specimen TCGA-DJ-A3UV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f97c1b2-583e-4c22-8f40-dbb5a4181878.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UV-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UV-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99d34ff4-d03c-424d-9f4c-dd45e874230b

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSGALNACT2 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.415); catalogued as COSV100989855, COSV65676025; called by muse, mutect2, varscan2
- HHEX | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51105760, COSV99263039; called by muse, mutect2, varscan2
- STON2 | c.821A>G p.N274S (on ENST00000649389 / NM_001366849.2; = p.N217S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99965175; called by muse, mutect2, varscan2
- CX3CL1 | c.399C>T p.G133= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs373115385; called by muse, mutect2, varscan2
- GCN1 | c.7599C>G p.G2533= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV100326012; called by muse, mutect2, varscan2
- HPS1 | c.888C>T p.L296= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs942950400, COSV57270534; called by muse, mutect2, varscan2
- HPS1 | c.852G>A p.G284= | Silent (SNP) | VAF 55/335 reads (16%) | catalogued as COSV57268431; called by muse, mutect2
